Gene-level copy-number profile of tumor specimen TCGA-LN-A49X-01A from TCGA case TCGA-LN-A49X, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 44.2 years (16,154 days).
Specimen TCGA-LN-A49X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.58b5034d-d390-4881-ad56-14ea1de22c05.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/034a8e7d-8763-4b89-8c47-07848b84530c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 177; copy number 1: 7,948; copy number 2: 40,494; copy number 3: 4,683; copy number 4: 5,198; copy number 5: 1,148; copy number 8: 34; copy number 11: 65; copy number 12: 66.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49X-01A-31D-A25X-01): tumor purity 0.28, ploidy 2.35, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 177 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:21,370,064–23,145,021, 177 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,313 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:96,798,278–122,887,691, 490 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr5:12,297,399–45,895,970, 468 genes, copy number 5 (broad region; genes not listed).
- chr7:89,754,620–95,296,415, 93 genes, copy number 8–11 (within-gene range 3–11) (broad region; genes not listed).
- chr11:64,394,342–67,683,058, 227 genes, copy number 5 (broad region; genes not listed).
- chr11:81,842,435–81,987,813, 3 genes, copy number 5: AP002802.2, MIR4300, AP002802.1.
- chr11:82,729,940–83,423,516, 29 genes, copy number 5: FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:83,643,602–83,815,263, 3 genes, copy number 5: DLG2-AS2, AP002370.1, LDHAL6DP.

Autosomal genes at a single copy (total copy number 1): 7,095. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
